Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA05, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA05-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
JW 2/13/14

Date of procurement:

Pathohistological diagnosis

Seminoma testis (pT2 NXMX), left testicle

Description:

Partially cut testicle with tumor, 7.5x5x5 cm in size (testicle and tumor combined) with 4.5 cm long funiculus was received. On the inner part of the testicle at the cut we see white, medium solid tumor 7x4.8x4.5 cm in size that permeates almost the entire testicle and spreads into tunica albuginea.

Histologically, the tumor is mostly made of tumor cells with round and oval bright nuclei with pronounced smaller nuclei with medium abundant bright and pink cytoplasm. Immunohistochemically speaking, tumor cells are positive for PLAP. In tumor we find up to two mitosis per microscope large visual field. Tumor tissue is partially necrotic. The tumor is surrounded by connecting tissue that is partially permeated with abundant infiltrates made of lymphocytes, plasma cells, macrophages and individual multinuclear giant cells of foreign substance type.

Tumor tissue is found in individual blood vessels.

The tumor infiltrates tunica albuginea and partially infiltrates epididymis and penetrates into rete testis. Funiculus contains no tumor.

In testicular tissue surrounding the tumor we find atrophic channels. Unclassified intratubular germ cell neoplasia (IGCNU) is not observed.

Separate in the same container a grayish tissue cut 8x3.5x1.5 cm was also received. This sample histologically contains fat and connecting tissue with blood vessels without tumor tissue.

Source: NCI Genomic Data Commons file 27de7348-f07b-4f09-8fe0-984185e9e467 (TCGA-ZM-AA05.91933905-9569-4998-A326-D314234C1808.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).